Somatic mutation profile of tumor specimen TARGET-10-PARHLM-09A (aliquot TARGET-10-PARHLM-09A-01D) from TARGET case TARGET-10-PARHLM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (797 days).
Specimen TARGET-10-PARHLM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2db634f7-80c6-4186-ad57-e195a7e132b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHLM-10A (Blood Derived Normal), aliquot TARGET-10-PARHLM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/838776b4-7665-46b3-bcd6-76a6dd25f09c

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NMBR | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- TENM3 | c.4568T>C p.I1523T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PQBP1 | c.330G>A p.S110= | Silent (SNP) | VAF 59/203 reads (29%) | catalogued as COSV54429752; called by muse, mutect2, varscan2
- PARD6G | c.295+19575G>A | Intron (SNP) | VAF 15/29 reads (52%) | catalogued as rs1220803491; called by muse, mutect2, varscan2
